Somatic mutation profile of tumor specimen TARGET-10-PAPHIG-09A (aliquot TARGET-10-PAPHIG-09A-01D) from TARGET case TARGET-10-PAPHIG, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.4 years (882 days).
Specimen TARGET-10-PAPHIG-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 845b03b3-40c5-4880-8448-ce2cb1d9d111.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPHIG-14A (Bone Marrow Normal), aliquot TARGET-10-PAPHIG-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2d7bf92c-82ff-4e59-bd20-b83dc295efca

The open-access MAF lists 29 somatic variants for this specimen: 23 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 3, Nonsense Mutation 2, 3'Flank 1, RNA 1, In Frame Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.5039_5041del p.S1680del | In Frame Del (DEL) | VAF 46/152 reads (30%) | hotspot (GDC flag); catalogued as rs587783502; called by pindel, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 36/144 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- BRAP | c.889G>T p.D297Y | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV59538120; called by muse, mutect2
- BRSK2 | c.1472G>T p.R491L | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV57539690; called by muse, mutect2, varscan2
- CBL | c.1247G>C p.C416S | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757456261, COSV50630179, COSV50657213, COSV99875605; called by muse, varscan2
- CCDC89 | c.413G>T p.R138L | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.521); catalogued as rs777244675, COSV100320857; called by mutect2, varscan2
- CHAT | c.1681C>T p.R561* | Nonsense Mutation (SNP) | VAF 36/111 reads (32%) | catalogued as rs1458796820; called by muse, mutect2, varscan2
- COL14A1 | c.4974G>T p.E1658D | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.974); catalogued as rs750810651, COSV52859027; called by muse, mutect2, varscan2
- CPEB1 | c.440G>A p.R147H (on ENST00000617958; = p.R87H on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.017); catalogued as COSV55619431, COSV99917926; called by muse, mutect2, varscan2
- FOXB2 | c.41C>T p.P14L | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1209607680, COSV65022871; called by muse, mutect2, varscan2
- GABRG3 | c.951C>A p.D317E | Missense Mutation (SNP) | VAF 42/144 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61529200; called by muse, mutect2, varscan2
- KIF26B | c.4857C>A p.S1619R | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.54); PolyPhen benign (0.052); catalogued as rs1309410599; called by muse, mutect2
- NPC1L1 | c.803G>A p.R268H | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs200554468, COSV99212621; called by muse, mutect2, varscan2
- OR51G2 | c.283C>T p.R95* | Nonsense Mutation (SNP) | VAF 31/69 reads (45%) | catalogued as rs146466233; called by muse, mutect2
- SEPTIN12 | c.889G>T p.D297Y | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51616146; called by muse, mutect2, varscan2
- TMPRSS6 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 58/165 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.386); catalogued as rs752163489, COSV104415970; ClinVar: uncertain significance; called by muse, varscan2
- UNC13C | c.1661C>T p.S554F | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs866109444; called by muse, mutect2, varscan2
- CEP104 | c.1022T>G p.L341R | Missense Mutation (SNP) | VAF 54/175 reads (31%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- NBEAL2 | c.3382C>A p.Q1128K | Missense Mutation (SNP) | VAF 6/89 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.091); called by muse, mutect2
- NT5DC3 | c.745G>T p.D249Y | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- RHBDD2 | c.725C>A p.A242D | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.282); called by muse, mutect2
- SEMG1 | c.923A>G p.D308G | Missense Mutation (SNP) | VAF 73/185 reads (39%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- TMEM94 | c.1919C>A p.T640N | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); called by muse, mutect2
- PCDHB7 | c.1629C>T p.S543= | Silent (SNP) | VAF 58/190 reads (31%) | catalogued as COSV50755334; called by muse, varscan2
- PRRG1 | c.441C>A p.G147= | Silent (SNP) | VAF 3/27 reads (11%) | called by muse, mutect2
- TRAF6 | c.819G>A p.L273= | Silent (SNP) | VAF 10/30 reads (33%) | called by muse, mutect2, varscan2
- AC078880.2 | n.112C>A | RNA (SNP) | VAF 4/38 reads (11%) | called by muse, varscan2
- CICP28 | chr7:56811947 A>G | 3'Flank (SNP) | VAF 23/63 reads (37%) | catalogued as rs1554353556; called by muse, mutect2, varscan2
- STAG2 | c.3467+90C>A | Intron (SNP) | VAF 4/36 reads (11%) | called by muse, mutect2
